Somatic mutation profile of tumor specimen TCGA-AA-3494-01A (aliquot TCGA-AA-3494-01A-01D-1408-10) from TCGA case TCGA-AA-3494, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 55.0 years (20,089 days).
Specimen TCGA-AA-3494-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f43387a-d4f6-4294-81de-84cad9ccee07.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3494-11A (Solid Tissue Normal), aliquot TCGA-AA-3494-11A-01D-2188-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cff8e567-0cdb-435a-a8c7-8c9f235dd680

The open-access MAF lists 94 somatic variants for this specimen: 75 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 18, Nonsense Mutation 3, Frame Shift Del 2, Frame Shift Ins 1, Splice Site 1, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM5 | c.1303T>C p.Y435H | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1567346226; called by muse, mutect2, varscan2
- ADAMTS12 | c.1789C>T p.R597C | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as rs752356049, COSV61272997; called by muse, mutect2, varscan2
- ALDOA | c.746G>A p.G249E (on ENST00000642816 / NM_001243177.4; = p.G195E on NM_184041.5) | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV57632343; called by muse, mutect2, varscan2
- ANKRD27 | c.2254G>A p.A752T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); catalogued as rs562931288, COSV100043172, COSV60136505; called by muse, mutect2, varscan2
- AP4B1 | c.2150C>T p.T717M | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as rs199879996; called by muse, mutect2, varscan2
- APC | c.3925G>T p.E1309* | Nonsense Mutation (SNP) | VAF 35/46 reads (76%) | catalogued as rs1321583762, CD084022, CD941590, CM920052, COSV57321386, COSV57334587, COSV99971982; called by muse, mutect2, varscan2
- ARC | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 29/34 reads (85%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV63077957; called by muse, mutect2, varscan2
- ARHGEF18 | c.2210G>A p.R737H (on ENST00000359920 / NM_001130955.2; = p.R633H on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs878978658; called by muse, mutect2, varscan2
- C19orf57 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs144556741; called by muse, mutect2, varscan2
- CACNA1E | c.2758C>T p.R920C | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.68); catalogued as rs769232172, COSV100702048, COSV62382687; called by muse, mutect2, varscan2
- CACNB4 | c.1532G>T p.G511V | Missense Mutation (SNP) | VAF 68/148 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as rs758710904, COSV52391435; called by muse, mutect2, varscan2
- CCDC142 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.288); catalogued as rs1028896928; called by muse, mutect2, varscan2
- CCDC77 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.042); catalogued as rs751274633; called by muse, mutect2, varscan2
- CDKL1 | c.334C>G p.L112V | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1010755627; called by muse, mutect2, varscan2
- COL27A1 | c.2938G>A p.E980K | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61926976; called by muse, mutect2, varscan2
- CR1 | c.5363C>A p.T1788N | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.326); catalogued as COSV65455872, COSV65457190; called by muse, mutect2, varscan2
- DDR2 | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs754868982, COSV63370876; called by muse, mutect2, varscan2
- DRAM2 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 77/140 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as rs145044841, COSV54415436; called by muse, mutect2, varscan2
- DUOX2 | c.3940G>A p.E1314K | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs759698581; called by muse, mutect2, varscan2
- GNL1 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV64835109; called by muse, mutect2, varscan2
- HIPK1 | c.3155C>G p.S1052* (on ENST00000369558 / NM_001369806.1; = p.S658* on NM_181358.2) | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as COSV61246917; called by muse, mutect2, varscan2
- ITGAL | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs370478656; called by muse, mutect2, varscan2
- KCNU1 | c.2474G>A p.G825E | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as COSV67754441, COSV67758064; called by muse, mutect2, varscan2
- KRT33A | c.1082del p.E361Gfs*? | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | catalogued as COSV50365982; called by mutect2, pindel, varscan2
- MAP3K2 | c.987G>T p.R329S | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.071); catalogued as COSV100789349; called by muse, mutect2, varscan2
- MGAT5B | c.739G>A p.G247R | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as rs199861646; called by muse, mutect2, varscan2
- MRPS23 | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs761410726, COSV58032469; called by muse, mutect2, varscan2
- MYH11 | c.106G>A p.V36I | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs959014769, COSV55547746, COSV55567104; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NDUFAF2 | c.410A>G p.Y137C | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.43); catalogued as COSV56938261; called by muse, mutect2, varscan2
- NFYA | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58198251; called by muse, mutect2, varscan2
- NTRK2 | c.1160G>A p.G387D | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs551310223, COSV52858919; called by muse, mutect2, varscan2
- OR5H14 | c.106C>A p.L36I | Missense Mutation (SNP) | VAF 66/294 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV101454198; called by muse, mutect2, varscan2
- PAPPA2 | c.1730T>A p.L577Q | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62775607; called by muse, mutect2, varscan2
- PKD1 | c.4604G>A p.R1535H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.035); catalogued as rs147919184, COSV51927005; called by muse, mutect2, varscan2
- PLCZ1 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781075636, COSV56859649; called by muse, mutect2, varscan2
- PNLIP | c.1114A>T p.I372L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs1192685814; called by muse, mutect2, varscan2
- PSAPL1 | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1266441451; called by muse, mutect2, varscan2
- PSRC1 | c.797C>T p.P266L (on ENST00000409138 / NM_001363309.1; = p.P236L on NM_032636.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.095); catalogued as rs760943124, COSV64021140; called by muse, mutect2, varscan2
- ROBO2 | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.311); catalogued as rs746238322, COSV59903872; called by muse, mutect2, varscan2
- SARS2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 18/29 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as rs756872754; called by muse, mutect2, varscan2
- SCN10A | c.4138C>T p.R1380W | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs371600996; called by muse, mutect2, varscan2
- SDE2 | c.547G>C p.V183L | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV55250747; called by muse, mutect2, varscan2
- SNPH | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.282); catalogued as COSV60588787; called by muse, mutect2, varscan2
- SPRY3 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as rs748214599, COSV57142186; called by muse, mutect2, varscan2
- THSD7A | c.3364G>A p.V1122M | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.904); catalogued as rs758123945, COSV70268688; called by muse, mutect2, varscan2
- TMEM186 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs140742433; called by muse, mutect2, varscan2
- TRIM48 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 121/551 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs549443392; called by muse, mutect2, varscan2
- TSPAN14 | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV59368347; called by muse, mutect2, varscan2
- ADCY1 | c.1280A>C p.N427T | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- BLM | c.2876G>T p.R959L | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRINP2 | c.1457T>G p.L486R | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- C2CD6 | c.431G>A p.C144Y | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CHRNA1 | c.893T>C p.L298S (on ENST00000261007 / NM_001039523.3; = p.L273S on NM_000079.4) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CPD | c.2011C>T p.H671Y | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPNE1 | c.826G>C p.D276H (on ENST00000352393; = p.D281H on NM_003915.5) | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CRIM1 | c.738G>T p.E246D | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- DZIP1L | c.816dup p.L273Ifs*5 | Frame Shift Ins (INS) | VAF 60/125 reads (48%) | called by mutect2, varscan2
- ELAC1 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- FAAP100 | c.2515A>G p.T839A | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM118A | c.739T>A p.F247I | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- FSHR | c.1412T>C p.I471T | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NXT2 | c.401T>G p.F134C (on ENST00000372106 / NM_001242617.2; = p.F189C on NM_018698.5) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- OR11L1 | c.277T>G p.S93A | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- OR1L4 | c.783del p.F261Lfs*9 | Frame Shift Del (DEL) | VAF 35/126 reads (28%) | called by mutect2, pindel, varscan2
- PUM1 | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- PYM1 | c.41A>G p.K14R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- SEC24D | c.398-1G>C p.X133_splice | Splice Site (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2, varscan2
- SGSM1 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SH3GL3 | c.944C>T p.T315I | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.395); called by muse, varscan2
- TRAV22 | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM59 | c.760G>C p.V254L | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTK | c.542A>C p.E181A | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- USP15 | c.1570G>C p.D524H (on ENST00000280377 / NM_001351159.2; = p.D495H on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VPS13A | c.6917C>G p.T2306S | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- ZFYVE26 | c.1798G>A p.A600T | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ADIPOR1 | c.321C>T p.N107= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as rs377163409, COSV61851279; called by muse, mutect2, varscan2
- AHNAK2 | c.9288C>T p.D3096= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as rs369645081; called by muse, mutect2, varscan2
- AIMP2 | c.399C>T p.L133= | Silent (SNP) | VAF 24/45 reads (53%) | called by muse, mutect2, varscan2
- ALS2 | c.489G>A p.L163= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as rs759299836; called by muse, mutect2, varscan2
- ATCAY | c.969C>T p.Y323= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs751742218, COSV56655764; called by muse, mutect2, varscan2
- CDH18 | c.1140A>C p.P380= | Silent (SNP) | VAF 26/110 reads (24%) | called by muse, mutect2, varscan2
- CNTN6 | c.162T>A p.G54= | Silent (SNP) | VAF 38/138 reads (28%) | called by muse, mutect2, varscan2
- CYP11B2 | c.1488C>G p.L496= | Silent (SNP) | VAF 20/126 reads (16%) | called by muse, mutect2, varscan2
- ESR1 | c.1632G>T p.L544= | Silent (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2, varscan2
- GAPVD1 | c.3912C>T p.N1304= (on ENST00000394104; = p.N1313= on NM_015635.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as rs777272077; called by muse, mutect2, varscan2
- HDGFL1 | c.744C>T p.R248= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs762211928, COSV100014494; called by mutect2, varscan2
- LRIG2 | c.1956C>T p.H652= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as rs1016133487; called by muse, mutect2
- OBSCN | c.7368G>A p.S2456= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs377749787; called by muse, mutect2, varscan2
- OLFM3 | c.939C>A p.I313= (on ENST00000338858 / NM_001288821.1; = p.I293= on NM_058170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/64 reads (30%) | called by muse, mutect2, varscan2
- PLA2G2D | c.24G>T p.G8= | Silent (SNP) | VAF 98/190 reads (52%) | catalogued as COSV64282101; called by muse, mutect2, varscan2
- PLOD2 | c.948C>T p.D316= | Silent (SNP) | VAF 28/165 reads (17%) | called by muse, mutect2, varscan2
- SARDH | c.2412G>A p.P804= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs763155594, COSV100898523; called by muse, mutect2, varscan2
- ZFHX4 | c.5295T>A p.P1765= | Silent (SNP) | VAF 12/115 reads (10%) | catalogued as rs1328010157; called by muse, mutect2, varscan2
- KNOP1P1 | n.428G>C | RNA (SNP) | VAF 16/92 reads (17%) | catalogued as rs573381234; called by muse, mutect2, varscan2
